Somatic mutation profile of tumor specimen 0DQB2Y from CCDI case PBCEND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 12.5 years (4,558 days).
Specimen 0DQB2Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f40adf5-8f29-4c4f-bf0d-b13dddc1ce5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQB22 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c91d7c5-898b-4139-baa3-0bcef04ee6b6

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LNPEP | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 335/848 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs779310728; called by muse, mutect2, varscan2
- MTMR6 | c.1553A>G p.N518S | Missense Mutation (SNP) | VAF 60/521 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV67810195; called by muse, mutect2, varscan2
- MYLK4 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 50/558 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs138344110; called by muse, mutect2
- ACAD10 | c.525T>A p.F175L | Missense Mutation (SNP) | VAF 50/650 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KMT2E | c.2013C>T p.V671= | Silent (SNP) | VAF 226/710 reads (32%) | called by muse, mutect2, varscan2
- NPTX1 | c.738C>T p.S246= | Silent (SNP) | VAF 188/482 reads (39%) | called by muse, mutect2, varscan2
- TYW1B | c.30C>T p.L10= | Silent (SNP) | VAF 233/682 reads (34%) | catalogued as rs781913574; called by muse, mutect2, varscan2
- ARNT2 | c.622+84T>C | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, varscan2
